Somatic mutation profile of tumor specimen C3N-04094-01 (aliquot CPT0285460007) from CPTAC case C3N-04094, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.7 years (14,514 days).
Specimen C3N-04094-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ea5764e-a790-447f-9da4-d77e4bea8da4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04094-31 (Blood Derived Normal), aliquot CPT0285490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/909eccb9-b23b-411a-b9a5-ab5867bde009

The open-access MAF lists 57 somatic variants for this specimen: 35 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, RNA 4, Intron 2, Nonsense Mutation 2, 5'Flank 1, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1L1 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs374192935; called by muse, mutect2
- ANO4 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 87/353 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs1449991413; called by muse, mutect2, varscan2
- CBLIF | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 168/539 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); catalogued as rs776516305; called by muse, mutect2, varscan2
- CFAP47 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs746688244, COSV52882671; called by muse, mutect2, varscan2
- COL6A3 | c.6869G>A p.R2290H | Missense Mutation (SNP) | VAF 153/509 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs398124131, COSV99796521; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs577827734, COSV68630908; called by muse, mutect2, varscan2
- DYNC1I2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.751); catalogued as rs1319542307, COSV99783869; called by muse, mutect2, varscan2
- EMP1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 96/423 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99916924; called by muse, mutect2, varscan2
- ERICH5 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs748448678, COSV59317260; called by muse, mutect2, varscan2
- FAT3 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs757467000, COSV99963766; called by muse, mutect2, varscan2
- HK3 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574382910; called by muse, mutect2, varscan2
- LILRB4 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs778903434, COSV54408733; called by muse, mutect2
- MSLNL | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as rs368868312; called by muse, mutect2, varscan2
- NEDD4 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs754182996, COSV59062275; called by muse, mutect2, varscan2
- PFAS | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1462433326; called by muse, mutect2, varscan2
- RASGRF1 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 68/307 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212733714, COSV69178489; called by muse, mutect2, varscan2
- RP1L1 | c.4699C>T p.R1567C | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762676280, COSV101222955; called by muse, mutect2, varscan2
- SCN10A | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370603046; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAFA2 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 39/182 reads (21%) | catalogued as COSV101352965, COSV101353930, COSV69178548; called by muse, mutect2, varscan2
- TCP11 | c.679C>T p.R227W (on ENST00000512012; = p.R165W on NM_018679.5) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs954988108, COSV55133879; called by muse, mutect2, varscan2
- AGAP3 | c.995C>T p.S332F (on ENST00000622464; = p.S368F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ANO5 | c.1681T>C p.F561L | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DLEC1 | c.736A>T p.K246* | Nonsense Mutation (SNP) | VAF 102/318 reads (32%) | called by muse, mutect2, varscan2
- FAM149A | c.1261G>A p.D421N (on ENST00000356371 / NM_001367768.2; = p.D130N on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, varscan2
- MAP11 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2
- OR5L2 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- OR8J1 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PCDHAC2 | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- PDCL2 | c.261A>C p.Q87H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); called by muse, mutect2
- PPP4R3C | c.1455C>A p.H485Q | Missense Mutation (SNP) | VAF 79/123 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PRKDC | c.3491_3492del p.C1164Ffs*25 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by pindel, varscan2
- SDS | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SUCNR1 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 106/314 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- UBP1 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 150/488 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WNT2 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ADAM2 | c.1626C>T p.C542= | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs201864039, COSV55866929, COSV99696491; called by muse, mutect2, varscan2
- AK7 | c.477G>A p.A159= | Silent (SNP) | VAF 56/144 reads (39%) | catalogued as rs757608679; called by muse, mutect2, varscan2
- CLCA4 | c.1512C>T p.N504= | Silent (SNP) | VAF 45/191 reads (24%) | catalogued as rs942081333, COSV99760113; called by muse, mutect2, varscan2
- CTSA | c.420G>A p.K140= | Silent (SNP) | VAF 82/343 reads (24%) | called by muse, mutect2, varscan2
- DHDDS | c.468C>T p.Y156= | Silent (SNP) | VAF 77/350 reads (22%) | catalogued as rs768075911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ILDR2 | c.583C>T p.L195= | Silent (SNP) | VAF 107/321 reads (33%) | called by muse, mutect2, varscan2
- IQCF2 | c.6G>A p.R2= | Silent (SNP) | VAF 55/188 reads (29%) | called by muse, mutect2, varscan2
- KIF1A | c.2313C>T p.A771= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as rs990063618; ClinVar: likely benign; called by muse, mutect2
- OLFML2B | c.282G>A p.A94= | Silent (SNP) | VAF 112/500 reads (22%) | catalogued as rs142507560, COSV99668327; called by muse, mutect2, varscan2
- SERPINA7 | c.744G>A p.V248= | Silent (SNP) | VAF 94/171 reads (55%) | catalogued as COSV100568317; called by muse, mutect2, varscan2
- SIGLEC9 | c.741C>T p.D247= | Silent (SNP) | VAF 97/279 reads (35%) | catalogued as rs774357117, COSV51582435, COSV51585838; called by muse, mutect2, varscan2
- SIPA1L2 | c.5121G>A p.L1707= | Silent (SNP) | VAF 36/242 reads (15%) | called by muse, mutect2, varscan2
- SYNE1 | c.14883G>A p.A4961= (on ENST00000367255 / NM_182961.4; = p.A4890= on NM_033071.3) | Silent (SNP) | VAF 42/185 reads (23%) | catalogued as rs539549948, COSV55086926; called by muse, mutect2, varscan2
- TDRD6 | c.645G>A p.A215= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as rs749887377; called by muse, mutect2
- C7orf66 | n.67G>T | RNA (SNP) | VAF 58/220 reads (26%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1792A>G | RNA (SNP) | VAF 59/569 reads (10%) | catalogued as rs1287096574; called by muse, mutect2, varscan2
- HSD3B7 | c.532-30G>T | Intron (SNP) | VAF 140/518 reads (27%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.1401C>A | RNA (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- PKD1P6 | n.4341C>A | RNA (SNP) | VAF 66/994 reads (7%) | called by muse, mutect2
- PRSS3 | c.-323C>T | 5'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- RNU6-389P | chr7:55685286 C>T | 5'Flank (SNP) | VAF 70/516 reads (14%) | catalogued as rs1363465398; called by muse, varscan2
- ZEB2 | c.73+5093G>C | Intron (SNP) | VAF 51/179 reads (28%) | called by muse, mutect2, varscan2
